Gene-level copy-number profile of tumor specimen TARGET-10-PASWNU-09A from TARGET case TARGET-10-PASWNU, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 15.3 years (5,580 days).
Specimen TARGET-10-PASWNU-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-ALL-P2.ac5b8d47-d891-5329-b269-6c39b443d89f.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-10-PASWNU-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 393 have no estimate.
https://portal.gdc.cancer.gov/files/4c844586-1f09-4c0b-a20b-a72da828364c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 537; copy number 1: 1,478; copy number 2: 57,235; copy number 3: 980.

Homozygous deletions (total copy number 0; autosomes only): 17 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:127,170,011–127,170,231, 1 gene: NIFKP9.
- chr7:38,239,580–38,311,808, 11 genes: TRGC2, TRGJ2, TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1.
- chr11:4,954,772–4,955,713, 1 gene: OR51A2.
- chr14:22,415,362–22,439,015, 4 genes: AC244502.3, TRDV2, TRDD1, TRDD2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 1,478. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
